Somatic mutation profile of tumor specimen 0DSJY8 from CCDI case PBCIEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,318 days).
Specimen 0DSJY8: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 648d92bb-b3c1-4713-b4a9-be3c3bce6967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSJYM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54153cca-3aa1-493e-8576-481fcd3ebd8c

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 46/274 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 28/336 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- CD109 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1213149278, COSV54649392; called by muse, mutect2, varscan2
- SPTBN1 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs762626546, COSV61693994; called by muse, mutect2, varscan2
- ZNF729 | c.531G>A p.K177= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- RGS10 | c.*63C>G | 3'UTR (SNP) | VAF 10/88 reads (11%) | catalogued as rs533878986; called by muse, mutect2, varscan2
- RNASEH2C | c.*789C>G | 3'UTR (SNP) | VAF 8/195 reads (4%) | called by muse, mutect2
